Somatic mutation profile of tumor specimen TCGA-EM-A2OY-01A (aliquot TCGA-EM-A2OY-01A-11D-A202-08) from TCGA case TCGA-EM-A2OY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 46.7 years (17,075 days).
Specimen TCGA-EM-A2OY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e67c2f4-7cd2-4d40-9bfe-7e53af001763.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2OY-10A (Blood Derived Normal), aliquot TCGA-EM-A2OY-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72097835-4cc9-4856-b1c3-57a3b7ee360f

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B1 | c.3038C>T p.A1013V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV54884250; called by muse, mutect2, varscan2
- CNPY4 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 61/344 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV53542456; called by muse, mutect2, varscan2
- COL12A1 | c.5690A>G p.Y1897C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV59396450; called by muse, mutect2, varscan2
- EXOC3L4 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as COSV66295547; called by muse, mutect2, varscan2
- GPR141 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758564434, COSV57732362; called by muse, mutect2, varscan2
- KRTAP4-2 | c.208T>C p.C70R | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66658501; called by muse, mutect2, varscan2
- LYPLAL1 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as rs770511971, COSV65106676; called by muse, mutect2, varscan2
- SHROOM2 | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66606868; called by muse, mutect2, varscan2
- TLL2 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV63572570; called by muse, mutect2, varscan2
- UBQLN3 | c.1792A>G p.M598V | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61164280; called by muse, mutect2, varscan2
- GRM6 | c.2446del p.Q816Rfs*5 | Frame Shift Del (DEL) | VAF 59/278 reads (21%) | called by mutect2, pindel, varscan2
- LRTM2 | c.228G>A p.L76= | Silent (SNP) | VAF 66/274 reads (24%) | catalogued as rs747673793, COSV54565090; called by muse, mutect2, varscan2
